Somatic mutation profile of tumor specimen TCGA-D3-A3MU-06A (aliquot TCGA-D3-A3MU-06A-11D-A21A-08) from TCGA case TCGA-D3-A3MU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.3 years (19,830 days).
Specimen TCGA-D3-A3MU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4422de2-e2b9-48d5-a377-99265846bb50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3MU-10A (Blood Derived Normal), aliquot TCGA-D3-A3MU-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d64d7018-3e70-484b-a44f-68af090c74fe

The open-access MAF lists 583 somatic variants for this specimen: 401 protein-altering or splice-affecting, 166 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 366, Silent 166, Nonsense Mutation 17, Splice Region 8, Intron 8, Splice Site 7, RNA 3, 5'UTR 2, 5'Flank 2, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 55/192 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 63/306 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372056603; called by muse, mutect2, varscan2
- ABI3BP | c.2088G>A p.G696= | Splice Region (SNP) | VAF 17/64 reads (27%) | catalogued as COSV52547996; called by muse, mutect2, varscan2
- ACE | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs755385604, COSV52011923; called by muse, mutect2, varscan2
- ACKR2 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as COSV56178170; called by muse, mutect2, varscan2
- ACSM4 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV68069035; called by muse, mutect2, varscan2
- ADAM7 | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758343247, COSV51545240; called by muse, mutect2, varscan2
- ADAMTS19 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50733874; called by muse, mutect2, varscan2
- ADAMTS2 | c.3248C>A p.P1083Q | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52388811; called by muse, mutect2
- ADGRB3 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.197); catalogued as COSV65391510; called by muse, mutect2, varscan2
- AJUBA | c.1399G>T p.G467C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as COSV52986381; called by muse, mutect2, varscan2
- AKAP8L | c.1047G>A p.K349= | Splice Region (SNP) | VAF 46/103 reads (45%) | catalogued as COSV68474346; called by muse, mutect2, varscan2
- AL645922.1 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100191230; called by muse, mutect2, varscan2
- ALMS1 | c.8957C>T p.P2986L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as rs1022866808, COSV52509517; called by muse, mutect2, varscan2
- ALPK1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 82/132 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); catalogued as COSV51583097; called by muse, mutect2, varscan2
- ANGPT1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs868669098, COSV52433932; called by muse, mutect2, varscan2
- ANK3 | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV55073952; called by muse, mutect2, varscan2
- APBB1IP | c.73-1G>A p.X25_splice | Splice Site (SNP) | VAF 26/95 reads (27%) | catalogued as COSV63303913; called by muse, mutect2, varscan2
- ARL6IP6 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.056); catalogued as rs755318004, COSV58443899; called by muse, mutect2
- ASH1L | c.7123C>T p.R2375C (on ENST00000368346 / NM_001366177.2; = p.R2370C on NM_018489.3) | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV64212393; called by muse, mutect2, varscan2
- ASIC2 | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV100726642; called by muse, mutect2, varscan2
- ASXL3 | c.6305C>T p.S2102F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV52476111; called by muse, mutect2, varscan2
- ATP2B2 | c.1534G>A p.E512K (on ENST00000352432; = p.E478K on NM_001683.5) | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.992); catalogued as COSV59505296; called by muse, mutect2, varscan2
- ATR | c.4406C>T p.T1469I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs747880325, COSV100638339; called by mutect2, varscan2
- BACH1 | c.188T>A p.I63N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99728371; called by muse, mutect2, varscan2
- BACH1 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.842); catalogued as COSV99728373; called by muse, mutect2, varscan2
- BAZ2B | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV58607844; called by muse, mutect2, varscan2
- BIRC6 | c.12019A>T p.K4007* | Nonsense Mutation (SNP) | VAF 34/61 reads (56%) | catalogued as COSV66042965; called by muse, mutect2, varscan2
- BTBD11 | c.2841-1G>A p.X947_splice (on ENST00000280758 / NM_001018072.2; = p.X484_splice on NM_001017523.2) | Splice Site (SNP) | VAF 27/111 reads (24%) | catalogued as COSV55034217; called by muse, mutect2, varscan2
- BTBD7 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54138404; called by muse, mutect2, varscan2
- C2CD3 | c.2736T>G p.D912E | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58098635; called by muse, mutect2, varscan2
- C6 | c.1292-1G>A p.X431_splice | Splice Site (SNP) | VAF 66/104 reads (63%) | catalogued as COSV54716230; called by muse, mutect2, varscan2
- C6 | c.1059G>C p.L353F | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54716243; called by muse, mutect2, varscan2
- C6orf58 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61667088; called by muse, mutect2, varscan2
- C8B | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV64779104; called by muse, mutect2, varscan2
- CACNA2D3 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as rs865798465, COSV55540495; called by muse, mutect2, varscan2
- CACNA2D4 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.577); catalogued as COSV54957701; called by muse, mutect2, varscan2
- CACNG3 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.653); catalogued as COSV50079592; called by muse, mutect2, varscan2
- CACNG6 | c.734C>T p.S245F (on ENST00000252729 / NM_145814.1; = p.S174F on NM_031897.2) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.265); catalogued as COSV53167861, COSV53168491; called by muse, mutect2, varscan2
- CCAR1 | c.1289A>G p.E430G | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV56273266; called by muse, mutect2, varscan2
- CCDC170 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV53344836; called by muse, mutect2, varscan2
- CCDC60 | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59544284; called by muse, mutect2, varscan2
- CCDC60 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59545358; called by muse, mutect2, varscan2
- CCDC70 | c.239_259del p.R80_E86del | In Frame Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs750263900; called by mutect2, varscan2
- CCT7 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99240927; called by muse, mutect2, varscan2
- CCT8L2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV63463536; called by muse, mutect2, varscan2
- CDH9 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 157/186 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50257951; called by muse, mutect2, varscan2
- CENPF | c.2879C>T p.S960F | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65278257; called by muse, mutect2, varscan2
- CEP350 | c.5353C>T p.R1785* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as rs1326776127, COSV100854499, COSV62608451; called by muse, mutect2, varscan2
- CERS3 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 36/162 reads (22%) | catalogued as rs747911784, COSV52566853; called by muse, mutect2, varscan2
- CFAP221 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.556); catalogued as rs536391548, COSV54657178, COSV99732738; called by mutect2, varscan2
- CHD1L | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV63615096; called by muse, mutect2, varscan2
- CHRNB4 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV99929440; called by muse, mutect2, varscan2
- CLEC18A | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as rs1378219220, COSV55345542; called by mutect2, varscan2
- CLYBL | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV59226979; called by muse, mutect2, varscan2
- CNBD1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs771986009, COSV72917438; called by muse, mutect2, varscan2
- CNGA2 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 61/77 reads (79%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV61705810; called by muse, mutect2, varscan2
- CNPPD1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs761363444, COSV55407752; called by muse, mutect2, varscan2
- CNTN4 | c.2729G>A p.W910* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as rs1426568021, COSV61879062; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- COL14A1 | c.5105G>A p.G1702E | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52850614; called by muse, mutect2, varscan2
- COL21A1 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769722166, COSV55163893, COSV99778638; called by muse, mutect2
- COL4A4 | c.4243G>A p.G1415S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61635518; called by muse, mutect2, varscan2
- COL4A4 | c.3215-1G>A p.X1072_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV61635522; called by muse, mutect2, varscan2
- COL6A2 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1258904789, COSV56013610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMP | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373759110, COSV55874292, COSV55876246; called by muse, mutect2, varscan2
- COMT | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747375116, COSV52890694; called by muse, mutect2, varscan2
- CPVL | c.963G>A p.T321= | Splice Region (SNP) | VAF 62/131 reads (47%) | catalogued as rs780578983, COSV55307110; called by muse, mutect2, varscan2
- CPZ | c.820C>A p.P274T (on ENST00000360986 / NM_001014447.3; = p.P263T on NM_003652.3) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV100249146, COSV59925169; called by muse, mutect2, varscan2
- CR2 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV65509229; called by muse, mutect2, varscan2
- CRB1 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.698); catalogued as rs764359208, COSV66329355, COSV66332707; called by muse, mutect2, varscan2
- CXCL10 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs755610178, COSV60660924; called by muse, mutect2, varscan2
- CYP1A1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65697975; called by muse, mutect2, varscan2
- CYP2C18 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV53673308; called by muse, mutect2, varscan2
- CYP4F11 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56129014; called by muse, mutect2, varscan2
- CYP4Z1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV61966297; called by muse, mutect2, varscan2
- CYRIA | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.12); catalogued as COSV62866683; called by muse, mutect2, varscan2
- CYTIP | c.477G>A p.T159= | Splice Region (SNP) | VAF 9/21 reads (43%) | catalogued as COSV51635549; called by muse, mutect2, varscan2
- DAAM2 | c.2051T>C p.L684P | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410682732, COSV51408167; called by muse, mutect2, varscan2
- DCD | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV53201171; called by muse, mutect2, varscan2
- DHRS1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV55385458; called by muse, mutect2, varscan2
- DMTF1 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 112/232 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1483714961, COSV58687656; called by muse, mutect2, varscan2
- DNAH17 | c.10958C>T p.P3653L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200811737, COSV67759770; called by muse, mutect2, varscan2
- DNAH5 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 275/313 reads (88%) | catalogued as COSV54245933; called by muse, mutect2, varscan2
- DNAH9 | c.6031G>A p.E2011K | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52370406; called by muse, mutect2, varscan2
- DNAJC27 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53096422; called by muse, mutect2, varscan2
- DOK3 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57254037; called by muse, mutect2, varscan2
- DPP10 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs764618439, COSV59679421; called by muse, mutect2, varscan2
- DSG4 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs868832775, COSV57396352; called by muse, mutect2, varscan2
- DYSF | c.5875C>T p.L1959F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50532336; called by muse, mutect2, varscan2
- EEPD1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV54202303; called by muse, mutect2, varscan2
- ELAC2 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100568555; called by muse, mutect2, varscan2
- ELOVL4 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); catalogued as rs1028928248, COSV63954522; called by muse, mutect2, varscan2
- EML5 | c.2635T>G p.F879V | Missense Mutation (SNP) | VAF 122/321 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV61350867; called by muse, mutect2, varscan2
- EOMES | c.1069A>C p.N357H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55414851; called by muse, mutect2, varscan2
- EPHB1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV67662615; called by muse, mutect2, varscan2
- ERAP1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 91/141 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57090776; called by muse, mutect2, varscan2
- ERBB4 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV53522339; called by muse, mutect2, varscan2
- ERBB4 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV53557978; called by muse, mutect2, varscan2
- ERICH3 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765565432, COSV58615239; called by muse, mutect2, varscan2
- ESRRG | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63176536; called by muse, mutect2, varscan2
- F13A1 | c.1111T>G p.W371G | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CS982177, COSV53565182; called by muse, mutect2, varscan2
- FAM83A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.596); catalogued as COSV52687472; called by muse, mutect2, varscan2
- FANCM | c.3615T>A p.D1205E | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57505254; called by muse, mutect2, varscan2
- FARP1 | c.456T>G p.N152K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100132200, COSV60345295; called by muse, mutect2, varscan2
- FAT3 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV53100807; called by muse, mutect2, varscan2
- FAT3 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53115002, COSV53159803; called by muse, mutect2, varscan2
- FGF19 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771545242, COSV53737084; called by muse, mutect2, varscan2
- FHOD3 | c.3965C>T p.P1322L (on ENST00000359247 / NM_001281739.3; = p.P1339L on NM_025135.5) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs546431597, COSV57184575; called by muse, mutect2, varscan2
- FILIP1 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227398173, COSV52738374; called by muse, mutect2, varscan2
- FLG | c.4577G>A p.G1526E | Missense Mutation (SNP) | VAF 173/728 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as rs776816341, COSV64235652; called by muse, mutect2, varscan2
- FLG | c.4576G>A p.G1526R | Missense Mutation (SNP) | VAF 174/733 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100911697; called by muse, mutect2, varscan2
- FLG | c.4072G>A p.G1358R | Missense Mutation (SNP) | VAF 599/1131 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV64240239; called by muse, mutect2, varscan2
- FLG2 | c.5803C>T p.P1935S | Missense Mutation (SNP) | VAF 114/401 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs767327149, COSV66171879; called by muse, mutect2, varscan2
- FMO3 | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV63008257; called by muse, mutect2, varscan2
- FOLH1 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57054924; called by muse, mutect2, varscan2
- FOXR1 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57653474; called by muse, mutect2, varscan2
- FREM2 | c.4541G>A p.G1514E | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV54848463; called by muse, mutect2, varscan2
- FSTL5 | c.2492A>C p.E831A | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60221410; called by muse, mutect2, varscan2
- FYB2 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV58583052, COSV58588110; called by muse, mutect2, varscan2
- GABRA2 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100734590, COSV62911664; called by muse, varscan2
- GALNT17 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 138/301 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61184126; called by muse, mutect2, varscan2
- GCDH | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55821864; called by muse, mutect2, varscan2
- GLOD5 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs782144572, COSV57489926; called by muse, mutect2, varscan2
- GOPC | c.601T>A p.Y201N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV50003944; called by muse, mutect2, varscan2
- GPM6A | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV54557011; called by muse, mutect2
- GPR158 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs1451450463, COSV66274647; called by muse, mutect2, varscan2
- GPX6 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.092); catalogued as COSV62658794; called by muse, mutect2, varscan2
- GRIA2 | c.1117A>C p.I373L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52402446; called by muse, mutect2, varscan2
- GRIK1 | c.1419C>G p.D473E | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV58729024; called by muse, mutect2
- GRIN2B | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs1301278088, COSV74207314; called by muse, mutect2, varscan2
- H3C13 | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 111/213 reads (52%) | catalogued as COSV58944781; called by muse, mutect2, varscan2
- HDAC9 | c.2648G>A p.G883E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67782705; called by muse, mutect2, varscan2
- HECW1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.009); catalogued as rs781520389, COSV67832131; called by muse, mutect2, varscan2
- HELZ2 | c.2620A>G p.T874A (on ENST00000467148 / NM_001037335.2; = p.T305A on NM_033405.3) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.199); catalogued as COSV64410336; called by muse, mutect2
- HERC5 | c.1082T>A p.L361* | Nonsense Mutation (SNP) | VAF 54/87 reads (62%) | catalogued as COSV52043626; called by muse, mutect2, varscan2
- HYDIN | c.13801G>A p.E4601K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.423); catalogued as rs1306778080, COSV66641575; called by muse, mutect2, varscan2
- IGLV1-47 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 189/356 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1334577524; called by muse, mutect2, varscan2
- IGSF10 | c.2999G>A p.S1000N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56790410; called by muse, mutect2, varscan2
- IL36G | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as rs760426074, COSV52078572; called by muse, mutect2, varscan2
- IL7R | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57412036; called by muse, mutect2, varscan2
- INPP5J | c.2409G>C p.Q803H (on ENST00000331075 / NM_001284285.2; = p.Q435H on NM_001002837.2) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs5997883, COSV53212035; called by muse, mutect2, varscan2
- IQGAP2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV57177349; called by muse, mutect2, varscan2
- IRF1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 127/187 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55378170; called by muse, mutect2, varscan2
- IRF6 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 87/159 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as CM092342, COSV65419435; called by muse, mutect2, varscan2
- ITGAE | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs764084572, COSV53998365; called by muse, mutect2, varscan2
- JAKMIP1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV51532343; called by muse, mutect2, varscan2
- KALRN | c.8644G>A p.D2882N (on ENST00000360013 / NM_001024660.4; = p.D1185N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52262712; called by muse, mutect2, varscan2
- KBTBD13 | c.1075G>C p.G359R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV101416697, COSV71351791; called by muse, mutect2
- KCNAB3 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as COSV58050906; called by muse, mutect2, varscan2
- KCND3 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1408698527, COSV56187517; called by muse, mutect2, varscan2
- KCNH4 | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99237454; called by muse, mutect2, varscan2
- KIF2B | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52133828; called by muse, mutect2, varscan2
- KLB | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as rs781587328, COSV57303036, COSV57304910; called by muse, mutect2, varscan2
- KLHL22 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV61022492; called by muse, mutect2, varscan2
- KLK13 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV50066984; called by muse, mutect2, varscan2
- KMT2E | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57572822, COSV57578308; called by muse, mutect2, varscan2
- KRT28 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV60685085; called by muse, mutect2, varscan2
- KY | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV71018431; called by muse, mutect2, varscan2
- L1TD1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.076); catalogued as COSV100776527, COSV63134129; called by muse, mutect2, varscan2
- LAMA1 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs866739457, COSV67539680; called by muse, mutect2, varscan2
- LCE1C | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64219060; called by muse, mutect2, varscan2
- LGMN | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374624844, COSV58404811; called by muse, mutect2, varscan2
- LHX5 | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441375365, COSV55663854; called by muse, mutect2, varscan2
- LILRA2 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52188978; called by muse, mutect2, varscan2
- LMNTD2 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV54245890; called by muse, mutect2, varscan2
- LNX1 | c.254A>C p.Q85P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55790434; called by muse, mutect2
- LRIT3 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs375438277; called by muse, mutect2, varscan2
- LRP1B | c.9814+1G>A p.X3272_splice | Splice Site (SNP) | VAF 34/132 reads (26%) | catalogued as COSV67261456; called by mutect2, varscan2
- LRP1B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs537488472, COSV67201409; called by muse, mutect2, varscan2
- LRRFIP1 | c.1139C>G p.S380C (on ENST00000392000 / NM_001137552.2; = p.S356C on NM_004735.4) | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV55255542; called by muse, mutect2, varscan2
- LTF | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51606643; called by muse, mutect2, varscan2
- LY75 | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV55105784; called by muse, mutect2, varscan2
- MAGEA10 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV54885493; called by muse, mutect2, varscan2
- MAGEC1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.448); catalogued as rs764103583, COSV53568059; called by muse, mutect2, varscan2
- MAK | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57567228; called by muse, mutect2, varscan2
- MAP3K9 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770841109, COSV67120353; called by muse, mutect2, varscan2
- MCMDC2 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV58039744; called by muse, mutect2, varscan2
- MDC1 | c.4358C>T p.P1453L | Missense Mutation (SNP) | VAF 185/396 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV64526616; called by muse, mutect2, varscan2
- METTL7B | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57699790; called by muse, mutect2, varscan2
- MGA | c.8014C>T p.P2672S (on ENST00000219905 / NM_001164273.1; = p.P2463S on NM_001080541.2) | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54960982; called by muse, mutect2, varscan2
- MGAM | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.337); catalogued as COSV72075386; called by muse, mutect2, varscan2
- MICAL3 | c.5023C>T p.P1675S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV71588285; called by muse, mutect2, varscan2
- MINAR1 | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1413218827, COSV59585693; called by muse, mutect2, varscan2
- MKI67 | c.9415G>A p.G3139R | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV64076230; called by muse, mutect2
- MMP27 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV99498537; called by muse, mutect2, varscan2
- MROH7 | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747900802, COSV64887264; called by muse, varscan2
- MS4A3 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV53934803; called by muse, mutect2, varscan2
- MTUS2 | c.3853G>A p.E1285K (on ENST00000612955 / NM_001366650.1; = p.E264K on NM_015233.6) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1317321912, COSV66421518; called by muse, mutect2, varscan2
- MUC16 | c.23531C>T p.S7844L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV67477313; called by muse, mutect2, varscan2
- MUC17 | c.9724C>T p.L3242F | Missense Mutation (SNP) | VAF 320/878 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs1438309624, COSV60284937; called by muse, mutect2, varscan2
- MUC21 | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 135/650 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV66221909; called by muse, mutect2, varscan2
- MUS81 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV57381250; called by muse, mutect2
- MUS81 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV57261290; called by mutect2, varscan2
- MXRA5 | c.7708C>T p.P2570S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV54232379, COSV54246225; called by muse, mutect2, varscan2
- MXRA5 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866233220, COSV54222468; called by muse, mutect2, varscan2
- MYH7 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62522714; called by muse, mutect2, varscan2
- MYO15A | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs773996873, CM1410846, COSV52755337; called by muse, mutect2, varscan2
- MYO1A | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV55656738; called by muse, mutect2, varscan2
- MYO1A | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55656751; called by muse, mutect2, varscan2
- MYO1F | c.2396A>C p.K799T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV57799064; called by muse, mutect2, varscan2
- NAE1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV51977910; called by muse, mutect2, varscan2
- NAP1L2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65172238; called by muse, mutect2, varscan2
- NEB | c.10234G>A p.E3412K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.287); catalogued as COSV50810111, COSV51449682, COSV99414366; called by muse, mutect2, varscan2
- NEB | c.8744C>T p.S2915F | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51449721; called by muse, mutect2, varscan2
- NEFH | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV60219804; called by muse, mutect2, varscan2
- NEXMIF | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50027658; called by muse, mutect2, varscan2
- NLRC5 | c.5144C>T p.S1715F | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs186267475, COSV52661262; called by muse, mutect2, varscan2
- NLRP9 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV60466770; called by muse, mutect2, varscan2
- NOBOX | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769328958, COSV56192923; called by muse, mutect2, varscan2
- NOL4 | c.1283C>A p.P428Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52358298; called by muse, mutect2, varscan2
- NONO | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 73/104 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52136749; called by muse, mutect2, varscan2
- NPSR1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 334/820 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289553312, COSV62206211; called by muse, mutect2, varscan2
- NPY5R | c.167T>A p.F56Y | Missense Mutation (SNP) | VAF 94/147 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV58453467; called by muse, mutect2, varscan2
- NRK | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV54591220, COSV99688066; called by muse, mutect2, varscan2
- NRXN3 | c.3163G>A p.E1055K (on ENST00000335750 / NM_001330195.2; = p.E682K on NM_004796.6) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59794308; called by muse, mutect2, varscan2
- NTNG1 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53984289; called by muse, mutect2, varscan2
- OBSCN | c.14059G>A p.A4687T | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1157487047, COSV99480788; called by muse, mutect2, varscan2
- OCIAD1 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV51902037; called by muse, mutect2, varscan2
- ODF1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 127/218 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53433940, COSV99573968; called by muse, mutect2, varscan2
- OGDHL | c.2948G>A p.G983E | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65100647; called by muse, mutect2, varscan2
- OR10A5 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1408053395, COSV55053595; called by muse, varscan2
- OR10A7 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs766727749, COSV58279311; called by muse, mutect2, varscan2
- OR10AG1 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56631774, COSV56634387; called by muse, mutect2, varscan2
- OR11A1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV65820757; called by muse, mutect2, varscan2
- OR11H12 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs551844965, COSV73569066; called by muse, mutect2, varscan2
- OR2G6 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 83/154 reads (54%) | catalogued as COSV58575478, COSV58575543; called by muse, mutect2, varscan2
- OR2M5 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 132/671 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV63545545, COSV63546003; called by muse, mutect2, varscan2
- OR4C11 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as COSV56352923; called by muse, mutect2, varscan2
- OR4Q3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV59177523; called by muse, mutect2, varscan2
- OR52N5 | c.473T>A p.F158Y | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV57699344; called by muse, mutect2, varscan2
- OR5AS1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57982912; called by muse, mutect2, varscan2
- OR5H6 | c.864G>T p.M288I (on ENST00000642105; = p.M272I on NM_001005479.2) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as COSV67351968; called by muse, mutect2, varscan2
- OR5M11 | c.807A>T p.E269D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV101602017, COSV73141980; called by muse, mutect2, varscan2
- OR9K2 | c.871C>T p.P291S (on ENST00000305377; = p.P269S on NM_001005243.1) | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as rs148051420; called by muse, mutect2, varscan2
- OTOGL | c.2563C>T p.P855S (on ENST00000547103; = p.P846S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV101509380; called by muse, mutect2, varscan2
- P3H2 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV60026563; called by muse, mutect2, varscan2
- PAPPA2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs749013840, COSV62772467, COSV62777922; called by muse, mutect2, varscan2
- PARD3B | c.3380C>T p.P1127L (on ENST00000406610 / NM_001302769.2; = p.P1058L on NM_057177.7) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62525992; called by muse, mutect2, varscan2
- PARP8 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV55864691; called by muse, mutect2, varscan2
- PARP8 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 90/159 reads (57%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.484); catalogued as rs756862351, COSV55865382; called by muse, mutect2, varscan2
- PARP8 | c.2507A>G p.E836G | Missense Mutation (SNP) | VAF 115/184 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55865389; called by muse, varscan2
- PCDHA13 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56536500; called by muse, mutect2, varscan2
- PCDHA13 | c.1813G>C p.A605P | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56536515; called by muse, mutect2
- PCDHA4 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 116/148 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as rs267600385, COSV63540193; called by muse, mutect2, varscan2
- PCDHAC2 | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.328); catalogued as COSV53864921; called by muse, mutect2, varscan2
- PCDHGB2 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV53931713; called by muse, mutect2, varscan2
- PCLO | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as rs755782082, COSV61658734; called by muse, mutect2, varscan2
- PCLO | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 101/299 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV61658759; called by muse, mutect2, varscan2
- PCLO | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV61658772; called by muse, mutect2, varscan2
- PDCD7 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372726216; called by muse, mutect2, varscan2
- PDE4DIP | c.4939C>T p.H1647Y | Missense Mutation (SNP) | VAF 87/377 reads (23%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.941); catalogued as COSV57721519; called by muse, mutect2, varscan2
- PDLIM2 | c.386G>A p.S129N (on ENST00000397760; = p.S379N on NM_021630.6) | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV56134798; called by muse, mutect2, varscan2
- PGAM2 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs770622502, COSV51979341; called by muse, mutect2, varscan2
- PGLYRP4 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.058); catalogued as COSV62836102; called by muse, mutect2, varscan2
- PKNOX2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 152/233 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV53552390; called by muse, mutect2, varscan2
- PLCB4 | c.3462G>A p.A1154= (on ENST00000278655 / NM_182797.3; = p.E1167K on NM_000933.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 20/60 reads (33%) | catalogued as rs761885301, COSV53800025; called by muse, mutect2, varscan2
- PLEKHG2 | c.3421C>T p.P1141S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.254); catalogued as rs1243572361, COSV52688455; called by muse, mutect2, varscan2
- PLEKHH2 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV56759479; called by muse, mutect2, varscan2
- PMEL | c.16A>T p.K6* | Nonsense Mutation (SNP) | VAF 113/291 reads (39%) | catalogued as COSV57187257; called by muse, mutect2, varscan2
- POM121 | c.2938C>T p.P980S (on ENST00000434423; = p.P715S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV57522494; called by muse, mutect2, varscan2
- POP1 | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV62893907; called by muse, mutect2, varscan2
- POTEE | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as rs748604049, COSV58233694; called by muse, mutect2, varscan2
- POTEF | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV62543525; called by muse, mutect2, varscan2
- POU6F2 | c.1427T>G p.V476G | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV68880460; called by muse, mutect2, varscan2
- PPL | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV62049928; called by muse, mutect2, varscan2
- PRAMEF1 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); catalogued as rs199886880; called by muse, mutect2, varscan2
- PRDM16 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 95/258 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV54604649; called by muse, mutect2, varscan2
- PREX2 | c.4541C>T p.S1514F | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs148366673, COSV55787039; called by muse, mutect2, varscan2
- PRLR | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV51496859; called by muse, mutect2, varscan2
- PRSS58 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV73488803; called by muse, mutect2, varscan2
- PSG9 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52484024; called by muse, mutect2, varscan2
- PSG9 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 173/481 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52484175; called by muse, mutect2, varscan2
- PSMC2 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV53008768; called by muse, mutect2, varscan2
- PTPN22 | c.1337G>A p.R446Q (on ENST00000359785 / NM_001193431.2; = p.R391Q on NM_012411.5) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs267597928, COSV63086220; called by muse, mutect2, varscan2
- PTPRC | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.037); catalogued as COSV61412107, COSV61422978; called by muse, mutect2, varscan2
- PTPRD | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV61973893; called by muse, mutect2, varscan2
- PTPRO | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55504902; called by muse, mutect2, varscan2
- PXDNL | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62496216; called by muse, mutect2, varscan2
- PXDNL | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.679); catalogued as COSV100681536, COSV62496219; called by muse, mutect2, varscan2
- RAD51AP2 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs776148641, COSV67588893; called by muse, mutect2, varscan2
- RASGRP4 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53097529; called by muse, mutect2
- RBMS1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62356281; called by muse, mutect2, varscan2
- RIMS1 | c.4565G>A p.G1522E | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53477093, COSV53480238; called by muse, mutect2, varscan2
- RIMS2 | c.1877G>A p.G626E (on ENST00000666250 / NM_001348490.2; = p.G434E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51713546; called by muse, mutect2, varscan2
- RIOK2 | c.916A>T p.T306S | Missense Mutation (SNP) | VAF 85/135 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV51614666; called by muse, mutect2, varscan2
- RIT2 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV56306652; called by muse, mutect2, varscan2
- ROBO3 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.74); catalogued as COSV67302343; called by muse, mutect2, varscan2
- RPGRIP1L | c.2566C>T p.L856F | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774095133, COSV50914167; called by muse, mutect2, varscan2
- RPL3L | c.852C>T p.I284= | Splice Region (SNP) | VAF 27/89 reads (30%) | catalogued as COSV51908088; called by muse, mutect2, varscan2
- RXFP2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV53633198, COSV53633693, COSV53639770; called by muse, mutect2
- RYR2 | c.10610G>A p.R3537K | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63706822; called by muse, mutect2, varscan2
- SAE1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54298099; called by muse, mutect2, varscan2
- SAMD3 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60777207; called by muse, mutect2, varscan2
- SARM1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV50229712; called by muse, mutect2, varscan2
- SCN11A | c.4729C>T p.P1577S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV56576161; called by muse, mutect2, varscan2
- SCN1A | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1553547528, COSV57667504, COSV57682921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1D | c.316C>T p.L106F (on ENST00000338555; = p.L270F on NM_001130413.4) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57643907; called by muse, mutect2, varscan2
- SCUBE1 | c.484+1G>A p.X162_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as COSV51815538; called by mutect2, varscan2
- SELL | c.728G>A p.G243E (on ENST00000650983; = p.G230E on NM_000655.5) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52552756; called by muse, mutect2
- SELPLG | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57314382; called by muse, mutect2, varscan2
- SEMA6C | c.1431C>T p.A477= | Splice Region (SNP) | VAF 84/278 reads (30%) | catalogued as COSV59006646; called by muse, mutect2, varscan2
- SEMG1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.973); catalogued as rs200558922, COSV99725337; called by muse, mutect2, varscan2
- SHANK1 | c.6053C>T p.S2018L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs779699079, COSV53259601; called by muse, mutect2, varscan2
- SHOC1 | c.1859A>T p.K620I | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV59506157; called by muse, mutect2, varscan2
- SIPA1 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67746383; called by muse, mutect2, varscan2
- SLC12A6 | c.560C>T p.T187I (on ENST00000354181 / NM_001365088.1; = p.T136I on NM_005135.2) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1275563766, COSV51628369; called by muse, mutect2, varscan2
- SLC16A2 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV52087899; called by muse, mutect2, varscan2
- SLC1A3 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54319302; called by muse, mutect2, varscan2
- SLC2A1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV65287842; called by muse, mutect2, varscan2
- SLC38A11 | c.442C>T p.P148S (on ENST00000409149 / NM_001351539.1; = p.P126S on NM_173512.2) | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV58055591; called by muse, mutect2, varscan2
- SLC44A1 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66026996; called by muse, mutect2, varscan2
- SLC5A5 | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55834946; called by muse, mutect2
- SLIT3 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 83/105 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as rs1364896968, COSV60620601; called by muse, mutect2, varscan2
- SMAD1 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV57471671; called by muse, mutect2, varscan2
- SMC1B | c.2060G>A p.G687D | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV62532732; called by muse, mutect2, varscan2
- SMC4 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58451171; called by muse, mutect2, varscan2
- SNAP91 | c.2575T>C p.F859L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV52131343; called by muse, mutect2, varscan2
- SORBS2 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777368592, COSV53011664; called by muse, mutect2, varscan2
- SP8 | c.1100A>G p.Y367C (on ENST00000361443 / NM_198956.4; = p.Y385C on NM_182700.6) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63866814; called by muse, mutect2, varscan2
- SPANXN2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 198/316 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs201039433, COSV65129217; called by muse, varscan2
- SPATA7 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV50419827; called by muse, mutect2, varscan2
- SPHKAP | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs749478558, COSV60884901; called by muse, mutect2, varscan2
- SPRED3 | c.347-1G>A p.X116_splice | Splice Site (SNP) | VAF 12/20 reads (60%) | catalogued as COSV58313697; called by muse, mutect2, varscan2
- SPRR2A | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 118/533 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV66991481; called by muse, mutect2, varscan2
- SPRR3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as rs772735138, COSV54880927; called by muse, varscan2
- SPRYD3 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56855534; called by muse, mutect2, varscan2
- SRL | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300418433, COSV68424159; called by muse, mutect2, varscan2
- STAG3 | c.1497C>G p.D499E | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57933941; called by muse, mutect2, varscan2
- STARD13 | c.1063G>A p.E355K (on ENST00000336934 / NM_001243476.3; = p.E237K on NM_052851.3) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs559020375, COSV55235339; called by muse, mutect2, varscan2
- STX1B | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.144); catalogued as COSV52681718; called by muse, mutect2, varscan2
- STYXL2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs778251840, COSV99609464; called by muse, mutect2, varscan2
- SULF2 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs147131391; called by muse, varscan2
- SVEP1 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57027654; called by muse, mutect2
- SYNE1 | c.1752G>A p.M584I (on ENST00000367255 / NM_182961.4; = p.M591I on NM_033071.3) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.07); catalogued as COSV54980883, COSV55071826; called by muse, mutect2, varscan2
- TACC2 | c.7810G>T p.E2604* (on ENST00000334433; = p.E682* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV53287620; called by muse, mutect2
- TACR3 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59207067; called by muse, mutect2, varscan2
- TAS2R14 | c.261T>G p.N87K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.727); catalogued as COSV67861472; called by muse, mutect2, varscan2
- TBC1D8B | c.1318C>T p.H440Y | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV52182417; called by muse, mutect2, varscan2
- TBX18 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1234961449, COSV63736399; called by muse, mutect2, varscan2
- TBX20 | c.300T>G p.I100M | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV101282392, COSV68782895; called by muse, mutect2, varscan2
- TBX20 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV101282393; called by muse, mutect2, varscan2
- TBX5 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV59866659; called by muse, varscan2
- TIAM2 | c.1572A>T p.E524D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs780985261, COSV59701345; called by muse, mutect2, varscan2
- TIMP4 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55139830; called by muse, mutect2, varscan2
- TLL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 124/214 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50265437; called by muse, mutect2, varscan2
- TMEM108 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 112/282 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.04); catalogued as rs780460288, COSV58865017; called by muse, mutect2, varscan2
- TMEM267 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 113/166 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV67993066; called by muse, mutect2, varscan2
- TMEM89 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56574695; called by muse, mutect2, varscan2
- TMX2 | c.358T>G p.C120G | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53555952; called by muse, mutect2, varscan2
- TNC | c.3379C>T p.R1127W | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs775276668, COSV60780537; called by muse, mutect2, varscan2
- TNN | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); catalogued as COSV53433320, COSV99510797; called by muse, mutect2, varscan2
- TNRC18 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101259469; called by muse, varscan2
- TP53BP1 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55507044; called by muse, mutect2, varscan2
- TP63 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV53212142; called by muse, mutect2, varscan2
- TRAF3IP3 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV50558168; called by muse, mutect2, varscan2
- TREML4 | c.507G>A p.R169= | Splice Region (SNP) | VAF 10/61 reads (16%) | catalogued as COSV58386072; called by muse, mutect2, varscan2
- TRIM49 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs756095582, COSV61671521; called by muse, mutect2, varscan2
- TRIOBP | c.4807G>A p.D1603N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV60382992; called by muse, mutect2, varscan2
- TRPC4 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV59013321; called by muse, mutect2, varscan2
- TRPV5 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as COSV54682869; called by muse, mutect2, varscan2
- TSPAN11 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV53820838; called by muse, mutect2
- TTN | c.86948T>A p.V28983D (on ENST00000591111; = p.V21559D on NM_003319.4) | Missense Mutation (SNP) | VAF 44/89 reads (49%) | PolyPhen benign (0.003); catalogued as COSV60274315; called by muse, mutect2, varscan2
- TTN | c.80770G>A p.E26924K (on ENST00000591111; = p.E19500K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | PolyPhen benign (0.005); catalogued as COSV60274353; called by muse, mutect2, varscan2
- TTN | c.44206G>A p.D14736N (on ENST00000591111; = p.D7312N on NM_003319.4) | Missense Mutation (SNP) | VAF 39/75 reads (52%) | PolyPhen probably damaging (0.998); catalogued as rs757542062, COSV60170585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.36823G>A p.E12275K (on ENST00000591111; = p.E4851K on NM_003319.4) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | PolyPhen benign (0.038); catalogued as COSV60274432; called by muse, mutect2
- TTN | c.18607G>A p.E6203K (on ENST00000591111; = p.E5276K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | PolyPhen benign (0.017); catalogued as COSV59914803, COSV60176535; called by muse, mutect2, varscan2
- TXNDC16 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.697); catalogued as COSV55986687; called by muse, mutect2, varscan2
- UBR4 | c.10646C>T p.S3549F | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64395986; called by muse, mutect2, varscan2
- UGT2B10 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55322847; called by muse, mutect2, varscan2
- UNC13C | c.2257C>T p.Q753* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV52912526; called by muse, mutect2, varscan2
- USP32 | c.1399A>T p.T467S | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56275276; called by muse, mutect2, varscan2
- VGLL4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV56080723; called by muse, mutect2, varscan2
- VWA3B | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as COSV68245915; called by muse, varscan2
- WDR18 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV52122583; called by muse, mutect2
- YME1L1 | c.2192G>T p.R731L (on ENST00000326799 / NM_139312.3; = p.R674L on NM_014263.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58761079; called by muse, mutect2, varscan2
- ZC3H3 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 95/186 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV52793166; called by muse, mutect2, varscan2
- ZDBF2 | c.5131G>A p.D1711N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.505); catalogued as rs770725241, COSV65629113; called by muse, mutect2, varscan2
- ZDHHC4 | c.724A>T p.T242S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as COSV100253987; called by muse, mutect2, varscan2
- ZDHHC4 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as rs755829928, COSV100253988; called by muse, mutect2, varscan2
- ZNF208 | c.3487C>T p.H1163Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV68111321; called by muse, mutect2, varscan2
- ZNF208 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV68101328, COSV68111329; called by muse, mutect2, varscan2
- ZNF341 | c.2435A>C p.E812A (on ENST00000375200 / NM_001282935.1; = p.E805A on NM_032819.4) | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV61010626; called by muse, mutect2, varscan2
- ZNF366 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 224/356 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV59218305; called by muse, mutect2, varscan2
- ZNF451 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62599457; called by muse, mutect2, varscan2
- ZNF479 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0.103); catalogued as COSV58637431, COSV58639649; called by muse, mutect2, varscan2
- ZNF695 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV60586047, COSV60587200; called by muse, mutect2, varscan2
- ZNF813 | c.1489T>G p.C497G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101124909; called by muse, mutect2, varscan2
- ZNF831 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV64044019; called by muse, mutect2, varscan2
- ZNF831 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 102/180 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780519662, COSV64044029, COSV64046872; called by muse, mutect2, varscan2
- ZNF883 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV71309206; called by muse, mutect2, varscan2
- ZPBP2 | c.176A>G p.K59R (on ENST00000348931 / NM_199321.3; = p.K37R on NM_198844.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV62375600; called by muse, mutect2, varscan2
- DHRS11 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- FAM160B2 | c.72_75dup p.F26Gfs*19 | Frame Shift Ins (INS) | VAF 92/213 reads (43%) | called by mutect2, pindel, varscan2
- KIR2DL1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.322); called by muse, mutect2
- MUC2 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.88); called by muse, mutect2, varscan2
- SLCO6A1 | c.1661del p.L554* | Frame Shift Del (DEL) | VAF 25/140 reads (18%) | called by mutect2, pindel, varscan2
- TRAV8-6 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TRBV2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACADVL | c.408C>T p.L136= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV50038730; called by muse, mutect2, varscan2
- ADAMTS12 | c.4623G>A p.K1541= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV61274817; called by muse, mutect2, varscan2
- ADGRL4 | c.1353C>T p.F451= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs1452989557, COSV66062953; called by muse, mutect2, varscan2
- ANK2 | c.5928C>T p.S1976= | Silent (SNP) | VAF 31/227 reads (14%) | catalogued as COSV52182233; called by muse, mutect2, varscan2
- ANK3 | c.10650G>A p.G3550= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV55075635; called by muse, mutect2, varscan2
- AR | c.2409G>A p.Q803= | Silent (SNP) | VAF 64/76 reads (84%) | catalogued as COSV65962545; called by muse, mutect2, varscan2
- ATP13A4 | c.1623G>A p.G541= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV55073888; called by muse, mutect2, varscan2
- ATP13A5 | c.1557G>A p.Q519= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV60873669; called by muse, mutect2
- ATR | c.4407C>T p.T1469= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs201300027, COSV100638292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAT2 | c.675C>T p.V225= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs772311876, COSV60273720; called by muse, mutect2, varscan2
- BRD9 | c.1365G>A p.T455= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs149025034; called by muse, mutect2
- BRINP1 | c.2139G>A p.G713= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as COSV56296505, COSV56307061; called by muse, mutect2, varscan2
- C7 | c.1308G>A p.V436= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV100495432, COSV57470929, COSV57479187; called by muse, mutect2, varscan2
- CABLES1 | c.1473C>T p.P491= (on ENST00000256925 / NM_001100619.2; = p.P226= on NM_138375.2) | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV56936527; called by muse, mutect2, varscan2
- CCDC170 | c.1056T>A p.I352= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV53344824; called by muse, mutect2, varscan2
- CCDC57 | c.2637G>A p.K879= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV60759738; called by muse, mutect2, varscan2
- CD300LD | c.510C>T p.F170= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV64710728; called by muse, mutect2, varscan2
- CHAT | c.1107G>A p.V369= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100340781, COSV60331064; called by muse, mutect2, varscan2
- CHRNB4 | c.1176C>T p.P392= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs142694602; called by muse, mutect2, varscan2
- CIART | c.963C>T p.I321= | Silent (SNP) | VAF 77/284 reads (27%) | catalogued as COSV51745803; called by muse, mutect2, varscan2
- CKMT1A | c.786G>A p.V262= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs760417315, COSV101376811; called by muse, mutect2, varscan2
- CLVS2 | c.696C>T p.N232= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV51567866; called by muse, mutect2, varscan2
- CPEB1 | c.1173C>T p.F391= (on ENST00000617958; = p.F331= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/86 reads (70%) | catalogued as COSV55617099; called by muse, mutect2, varscan2
- CREBBP | c.7281C>T p.V2427= | Silent (SNP) | VAF 105/274 reads (38%) | catalogued as rs764396354, COSV52136742; called by muse, mutect2, varscan2
- CRHR2 | c.1134G>A p.Q378= | Silent (SNP) | VAF 151/382 reads (40%) | catalogued as COSV59267454; called by muse, mutect2, varscan2
- CTSS | c.282C>T p.S94= | Silent (SNP) | VAF 79/352 reads (22%) | catalogued as rs752106590, COSV64566913; called by muse, mutect2, varscan2
- CYLC1 | c.1392G>A p.G464= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV61414586; called by muse, mutect2, varscan2
- CYP2A7 | c.537C>T p.S179= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV52504989; called by muse, mutect2, varscan2
- DAB1 | c.1287C>T p.S429= (on ENST00000371231; = p.S396= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV64696870; called by muse, mutect2, varscan2
- DNAH11 | c.13518T>G p.V4506= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV60974788; called by muse, mutect2, varscan2
- DNAH5 | c.11268G>A p.R3756= | Silent (SNP) | VAF 63/79 reads (80%) | catalogued as COSV54226088; called by muse, mutect2, varscan2
- DNAH9 | c.2112G>A p.L704= | Silent (SNP) | VAF 67/203 reads (33%) | catalogued as COSV52370395; called by muse, mutect2, varscan2
- DOK6 | c.159C>T p.F53= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV66931009; called by muse, mutect2, varscan2
- DRGX | c.45C>A p.T15= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs776683385, COSV65137308; called by muse, mutect2, varscan2
- DYSF | c.1338C>T p.I446= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV50532128; called by muse, mutect2, varscan2
- EFCAB5 | c.738G>A p.K246= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100300852, COSV57935305; called by muse, mutect2, varscan2
- ELAC2 | c.234C>T p.S78= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs1009598122, COSV100568554; called by muse, mutect2, varscan2
- ELOA2 | c.855G>A p.G285= | Silent (SNP) | VAF 78/329 reads (24%) | catalogued as COSV55306533; called by muse, mutect2, varscan2
- ELOA2 | c.234C>T p.L78= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV55299547; called by muse, mutect2, varscan2
- EP300 | c.4992C>T p.D1664= | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as COSV54342117; called by muse, mutect2, varscan2
- EPB42 | c.85C>A p.R29= (on ENST00000441366 / NM_001114134.2; = p.R59= on NM_000119.3) | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV55751104; called by muse, mutect2, varscan2
- EPHA4 | c.1662G>A p.S554= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs749546730, COSV56041658; called by muse, mutect2, varscan2
- EPS8L2 | c.222C>T p.A74= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV59349860; called by muse, mutect2, varscan2
- FAAP100 | c.1197G>A p.L399= | Silent (SNP) | VAF 92/218 reads (42%) | catalogued as COSV59887088; called by muse, mutect2, varscan2
- FAM155B | c.1173C>T p.F391= | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as COSV52937485; called by muse, mutect2, varscan2
- FATE1 | c.330C>T p.F110= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as rs1390710129, COSV64848907; called by muse, mutect2, varscan2
- FBXO39 | c.903C>T p.I301= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1208815242, COSV58621674, COSV58622799; called by muse, mutect2, varscan2
- FCRL5 | c.96C>T p.T32= | Silent (SNP) | VAF 76/250 reads (30%) | catalogued as COSV62518786; called by muse, mutect2, varscan2
- FLRT2 | c.780G>A p.Q260= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as COSV58148258; called by muse, mutect2, varscan2
- FMN2 | c.1695C>T p.I565= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV60422909, COSV60447910; called by muse, mutect2, varscan2
- GALNTL6 | c.1104G>A p.R368= | Silent (SNP) | VAF 53/286 reads (19%) | catalogued as COSV72491035; called by muse, mutect2, varscan2
- GGTLC2 | c.555C>T p.I185= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs1203107042; called by mutect2, varscan2
- GIMAP7 | c.45G>A p.G15= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as COSV57960344; called by muse, mutect2, varscan2
- GJC3 | c.804G>A p.Q268= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as COSV57209945; called by muse, mutect2, varscan2
- GLDN | c.729C>T p.P243= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs753424904, COSV59091897; called by muse, mutect2, varscan2
- GRM7 | c.2115C>T p.I705= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV63163115; called by muse, mutect2, varscan2
- HESX1 | c.456C>T p.I152= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV55843613; called by muse, mutect2, varscan2
- HNF1A | c.702G>A p.E234= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV57465902; called by muse, mutect2, varscan2
- IFITM3 | c.402G>A p.*134= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV60249837; called by muse, mutect2, varscan2
- IGF1R | c.3912C>T p.P1304= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs756274518, COSV51272575, COSV51323035; called by muse, mutect2, varscan2
- IGHA1 | c.627C>T p.P209= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs372595680; called by muse, mutect2, varscan2
- IGHG3 | c.579G>A p.V193= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as rs748142742; called by muse, mutect2, varscan2
- IGLL1 | c.387C>T p.N129= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV99968621; called by muse, mutect2
- INMT | c.231C>T p.S77= | Silent (SNP) | VAF 265/694 reads (38%) | catalogued as COSV50002407; called by muse, mutect2, varscan2
- INPP5F | c.2589C>T p.F863= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV62823093, COSV62823185; called by muse, mutect2, varscan2
- INTS3 | c.1038C>T p.R346= | Silent (SNP) | VAF 127/205 reads (62%) | catalogued as COSV59680784; called by muse, mutect2, varscan2
- IQCD | c.600T>A p.T200= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV55323197; called by muse, mutect2, varscan2
- ITGA10 | c.1635G>A p.Q545= | Silent (SNP) | VAF 76/309 reads (25%) | catalogued as rs1553747987, COSV65198769; called by muse, mutect2, varscan2
- IVL | c.159G>A p.V53= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as COSV64216854; called by muse, mutect2, varscan2
- KALRN | c.2169C>T p.D723= | Silent (SNP) | VAF 105/341 reads (31%) | catalogued as COSV53766357; called by muse, mutect2, varscan2
- KCNC2 | c.1629C>T p.D543= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs201944231; called by muse, mutect2, varscan2
- KLK13 | c.396C>T p.S132= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as rs779245038, COSV99335341; called by muse, mutect2, varscan2
- KLK6 | c.126G>A p.S42= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs753254086, COSV59566514; called by muse, mutect2, varscan2
- LANCL1 | c.1146C>T p.F382= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV52066612; called by muse, varscan2
- LHX9 | c.531G>A p.K177= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV61330873; called by muse, mutect2, varscan2
- LIG3 | c.1258C>T p.L420= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs1189429348, COSV52010183; called by muse, mutect2, varscan2
- LRP1B | c.8877G>A p.L2959= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV67261460, COSV67274326; called by muse, mutect2, varscan2
- LRRC14B | c.1146G>A p.L382= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52053240; called by muse, mutect2
- LUZP1 | c.2904C>T p.S968= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV56504373; called by muse, mutect2, varscan2
- M1AP | c.547C>T p.L183= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs764700893, COSV51847507, COSV99304427; called by muse, mutect2, varscan2
- MAD2L2 | c.378C>T p.F126= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV52418390; called by muse, mutect2, varscan2
- MAPK7 | c.1920C>T p.P640= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV55191488; called by muse, mutect2, varscan2
- MEGF10 | c.27G>A p.L9= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as COSV57254906; called by muse, mutect2, varscan2
- MGAT4C | c.966G>A p.E322= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as COSV59836519; called by muse, mutect2, varscan2
- MOCS2 | c.54G>T p.P18= | Silent (SNP) | VAF 133/238 reads (56%) | catalogued as COSV63741357; called by muse, mutect2, varscan2
- MPST | c.327C>T p.S109= (on ENST00000341116 / NM_001369904.2; = p.S129= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV62018410; called by muse, mutect2, varscan2
- MRAP2 | c.498C>T p.I166= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as rs777763534, COSV57633937, COSV57634207; called by muse, mutect2, varscan2
- MRPL39 | c.414G>A p.V138= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV56261791; called by muse, mutect2, varscan2
- MUC16 | c.29412G>A p.E9804= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV67485811; called by muse, mutect2, varscan2
- MYBPH | c.1383G>A p.G461= | Silent (SNP) | VAF 116/389 reads (30%) | catalogued as rs1327981468, COSV55143823; called by muse, mutect2, varscan2
- MYH4 | c.4776G>A p.R1592= | Silent (SNP) | VAF 72/174 reads (41%) | catalogued as COSV55118729; called by muse, mutect2, varscan2
- MYO16 | c.705G>A p.K235= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs761353796; called by muse, mutect2, varscan2
- MYPOP | c.1074C>T p.A358= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV56194785; called by muse, mutect2, varscan2
- NLRP4 | c.315G>A p.Q105= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV56721098; called by muse, mutect2, varscan2
- NOS1 | c.3858C>T p.F1286= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs372919678; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPC1L1 | c.2086C>T p.L696= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as COSV56929251; called by muse, mutect2, varscan2
- OBSCN | c.14058G>A p.T4686= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as rs746997337, COSV52810645; called by muse, mutect2, varscan2
- OMA1 | c.1047C>T p.F349= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV62256606; called by muse, mutect2, varscan2
- OPLAH | c.1639C>T p.L547= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV70679031; called by muse, mutect2, varscan2
- OR2J3 | c.144C>T p.I48= | Silent (SNP) | VAF 172/381 reads (45%) | catalogued as COSV65849541; called by muse, mutect2, varscan2
- OR5K4 | c.663C>T p.I221= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV61584183; called by muse, mutect2, varscan2
- OR5L2 | c.84C>T p.F28= | Silent (SNP) | VAF 115/358 reads (32%) | catalogued as COSV65724567; called by muse, mutect2, varscan2
- P3H1 | c.813T>C p.H271= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV52536714; called by muse, mutect2, varscan2
- PCDH11X | c.3090G>A p.E1030= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as rs143087998, COSV53438993; called by muse, mutect2, varscan2
- PCDHB2 | c.366G>A p.E122= | Silent (SNP) | VAF 63/74 reads (85%) | catalogued as COSV52036410; called by muse, mutect2, varscan2
- PCLO | c.3603G>A p.E1201= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV61658749; called by muse, mutect2, varscan2
- PHF19 | c.609C>G p.P203= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs774078703, COSV56490654; called by muse, varscan2
- PITPNM2 | c.3321C>T p.F1107= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs147908575; called by muse, mutect2, varscan2
- PIWIL3 | c.2613G>A p.P871= | Silent (SNP) | VAF 100/185 reads (54%) | catalogued as rs191388762; called by muse, mutect2, varscan2
- PLCE1 | c.297G>A p.A99= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs768443933, COSV53335915; called by muse, mutect2, varscan2
- PLEKHH2 | c.3423C>T p.T1141= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99174864; called by muse, mutect2, varscan2
- PLP2 | c.211C>T p.L71= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as COSV66240465; called by muse, mutect2, varscan2
- PLXNA4 | c.4833C>T p.S1611= | Silent (SNP) | VAF 127/266 reads (48%) | catalogued as COSV58153271; called by muse, mutect2, varscan2
- PROC | c.990C>T p.L330= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV52167791; called by muse, mutect2, varscan2
- PTCHD4 | c.1776C>T p.I592= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV59788085, COSV59794280; called by muse, mutect2, varscan2
- PTPRN2 | c.1275G>A p.R425= | Silent (SNP) | VAF 85/101 reads (84%) | catalogued as COSV67056581; called by muse, mutect2, varscan2
- QSOX1 | c.1389C>T p.S463= | Silent (SNP) | VAF 54/196 reads (28%) | catalogued as rs757632701, COSV62581419; called by muse, mutect2, varscan2
- RFX2 | c.1377C>T p.I459= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV57944694; called by muse, mutect2, varscan2
- RP1 | c.1023A>T p.I341= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV55124134; called by muse, mutect2, varscan2
- RP1 | c.5715C>T p.D1905= | Silent (SNP) | VAF 156/252 reads (62%) | catalogued as COSV55124143, COSV55128549; called by muse, mutect2, varscan2
- RTN1 | c.1794C>T p.I598= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1357874634, COSV50741532; called by mutect2, varscan2
- RYR2 | c.6957C>T p.V2319= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs768367111, COSV63706816; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINB7 | c.465G>A p.K155= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV60535390; called by muse, mutect2, varscan2
- SESN3 | c.585C>T p.V195= | Silent (SNP) | VAF 66/100 reads (66%) | catalogued as COSV53583533, COSV53586938; called by muse, mutect2, varscan2
- SKOR1 | c.162T>C p.S54= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV58249127; called by muse, mutect2, varscan2
- SLC17A9 | c.1242G>A p.G414= | Silent (SNP) | VAF 189/311 reads (61%) | catalogued as COSV64848076; called by muse, mutect2, varscan2
- SLC22A12 | c.579C>T p.A193= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV60573658; called by muse, mutect2, varscan2
- SLC22A14 | c.1581C>T p.I527= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as rs780227462, COSV56198977; called by muse, mutect2, varscan2
- SLC22A4 | c.1374C>T p.N458= | Silent (SNP) | VAF 26/461 reads (6%) | catalogued as COSV52359793; called by muse, mutect2
- SLC2A12 | c.1119C>A p.T373= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV51602038; called by muse, mutect2, varscan2
- SLC4A8 | c.2418C>T p.V806= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV60657166; called by muse, mutect2, varscan2
- SMOC1 | c.195C>T p.S65= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as COSV62762913; called by muse, mutect2, varscan2
- SNAP91 | c.2031C>T p.F677= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52116474; called by muse, mutect2, varscan2
- SNAP91 | c.444G>A p.V148= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV52119280; called by muse, mutect2, varscan2
- SPTA1 | c.4347G>A p.K1449= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV63757801; called by muse, mutect2, varscan2
- SPTB | c.5865G>A p.R1955= | Silent (SNP) | VAF 59/188 reads (31%) | catalogued as COSV67634409; called by muse, mutect2, varscan2
- SYNE1 | c.5619C>T p.F1873= (on ENST00000367255 / NM_182961.4; = p.F1880= on NM_033071.3) | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV55071791; called by muse, mutect2, varscan2
- TACC2 | c.6093C>T p.A2031= (on ENST00000334433; = p.A109= on NM_006997.4) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV53287600; called by muse, mutect2, varscan2
- TAS1R2 | c.1056G>A p.R352= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV64746702; called by muse, mutect2, varscan2
- TBC1D9 | c.519C>T p.V173= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as rs764416541, COSV71308482; called by muse, mutect2, varscan2
- TCL1A | c.72C>T p.F24= | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as rs779175388, COSV68085087; called by muse, mutect2, varscan2
- TEKT4 | c.1125C>T p.S375= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV54627602; called by muse, mutect2, varscan2
- TESPA1 | c.1341C>T p.L447= (on ENST00000316577 / NM_001098815.3; = p.L309= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as rs768186129, COSV57257889; called by muse, mutect2, varscan2
- TJP2 | c.1938G>T p.L646= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV55272088; called by muse, mutect2, varscan2
- TLR2 | c.759G>A p.K253= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1014260301, COSV52607732; called by muse, mutect2, varscan2
- TMEM154 | c.288C>T p.F96= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58591804; called by muse, mutect2, varscan2
- TNN | c.222C>T p.A74= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV53433278; called by muse, varscan2
- TNN | c.291G>A p.K97= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV53433307; called by muse, varscan2
- TNRC18 | c.2067C>T p.A689= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as COSV101259470; called by muse, mutect2, varscan2
- TPTE2 | c.945C>T p.I315= (on ENST00000400230 / NM_199254.2; = p.I238= on NM_130785.3) | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs746435666, COSV55026496; called by muse, mutect2, varscan2
- TRIT1 | c.1023C>T p.V341= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs774397936, COSV100381410, COSV57547303; called by muse, mutect2, varscan2
- TRPC7 | c.2247G>A p.L749= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV61462201; called by muse, mutect2, varscan2
- UROC1 | c.912G>A p.R304= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as rs267599594, COSV52031041; called by muse, mutect2, varscan2
- USP26 | c.2196C>T p.F732= | Silent (SNP) | VAF 53/66 reads (80%) | catalogued as COSV63708857, COSV63709522; called by muse, mutect2, varscan2
- USP6 | c.588C>T p.F196= | Silent (SNP) | VAF 71/202 reads (35%) | catalogued as COSV51493457; called by muse, mutect2, varscan2
- VCAM1 | c.81C>T p.I27= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as rs769862238, COSV54119336, COSV54119728; called by muse, mutect2, varscan2
- XKR3 | c.471C>T p.F157= | Silent (SNP) | VAF 160/319 reads (50%) | catalogued as COSV58886594; called by muse, mutect2, varscan2
- ZAN | c.1899C>T p.P633= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as rs1462791949, COSV61814234; called by muse, mutect2, varscan2
- ZBTB4 | c.2844C>T p.L948= | Silent (SNP) | VAF 151/476 reads (32%) | catalogued as rs1342477599, COSV60141903; called by muse, mutect2, varscan2
- ZBTB46 | c.732T>G p.P244= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV55513564; called by muse, mutect2, varscan2
- ZC3HC1 | c.1389C>T p.T463= | Silent (SNP) | VAF 99/268 reads (37%) | catalogued as COSV61299810; called by muse, mutect2, varscan2
- ZIM2 | c.402C>T p.F134= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV55644026, COSV55645932; called by muse, mutect2, varscan2
- ZNF556 | c.96C>T p.V32= | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as COSV56913726; called by muse, mutect2, varscan2
- ZNF569 | c.366A>G p.V122= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV57598342; called by muse, mutect2, varscan2
- ZNF804A | c.1362C>T p.S454= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV56461892; called by muse, mutect2, varscan2
- ZNF91 | c.1506C>T p.S502= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV56091109; called by muse, mutect2, varscan2
- AC024940.1 | n.3114del | RNA (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- ACAA2 | chr18:49814195 C>T | 5'Flank (SNP) | VAF 102/177 reads (58%) | catalogued as rs1017500307; called by muse, mutect2, varscan2
- AGAP7P | n.1674C>T | RNA (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- AGAP7P | n.1675C>T | RNA (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- AL645933.1 | chr6:31463998 C>T | 5'Flank (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2, varscan2
- AMPD2 | c.-139C>T | 5'UTR (SNP) | VAF 24/73 reads (33%) | catalogued as COSV56647335; called by muse, mutect2, varscan2
- ATP8A1 | c.451-3468G>A | Intron (SNP) | VAF 34/92 reads (37%) | catalogued as COSV100046541; called by muse, mutect2, varscan2
- GH2 | c.457-19C>T | Intron (SNP) | VAF 43/102 reads (42%) | catalogued as COSV60427605; called by muse, mutect2, varscan2
- GUCY1A2 | c.1836+29871G>A | Intron (SNP) | VAF 10/16 reads (63%) | catalogued as COSV56497990; called by muse, mutect2, varscan2
- MGAM | c.4618+1189C>T | Intron (SNP) | VAF 83/217 reads (38%) | catalogued as COSV101527561; called by muse, mutect2, varscan2
- NCF4 | c.758+90C>T | Intron (SNP) | VAF 82/163 reads (50%) | catalogued as rs756178255, COSV99957438; called by muse, mutect2, varscan2
- NCF4 | c.758+91C>T | Intron (SNP) | VAF 83/165 reads (50%) | catalogued as COSV99957440; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791603 C>T | 3'Flank (SNP) | VAF 98/152 reads (64%) | called by muse, mutect2, varscan2
- SCN2A | c.606-144C>T | Intron (SNP) | VAF 11/45 reads (24%) | catalogued as rs558474027, COSV51840169; called by muse, mutect2, varscan2
- TREML2 | c.-62C>T | 5'UTR (SNP) | VAF 20/61 reads (33%) | catalogued as COSV101530178; called by muse, mutect2, varscan2
- USH1C | c.1284+1128C>T | Intron (SNP) | VAF 13/41 reads (32%) | catalogued as rs780885203, COSV50032972, COSV99139617; called by muse, mutect2, varscan2
